Gene-level copy-number profile of specimen HCM-CSHL-0621-C18-85M from HCMI case HCM-CSHL-0621-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 72.0 years (26,307 days).
Specimen HCM-CSHL-0621-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 40b74f24-fab6-4e53-8983-8b28ac26fa21.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0621-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/10e5f2c0-4ed8-425d-9307-d05b3c675a23

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 14,633; copy number 2: 43,336; copy number 3: 873; copy number 6: 3.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:81,689,713–81,776,900, 2 genes: AL591368.1, RNU6-1035P.
- chr10:88,259,129–88,259,372, 1 gene: AL353149.1.
- chr18:50,457,887–51,643,939, 18 genes (within-gene range 0–1): RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,189,995–65,230,861, 3 genes, copy number 6: BMS1P12, AL512605.1, AL512605.2.

Autosomal genes at a single copy (total copy number 1): 11,786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
